Somatic mutation profile of tumor specimen TCGA-44-7662-01A (aliquot TCGA-44-7662-01A-11D-2063-08) from TCGA case TCGA-44-7662, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 61.7 years (22,543 days).
Specimen TCGA-44-7662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3addff79-e536-4bbc-8529-a30c0e8b5b83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-7662-10A (Blood Derived Normal), aliquot TCGA-44-7662-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/060badaa-6432-4366-a372-f42985923d07

The open-access MAF lists 603 somatic variants for this specimen: 475 protein-altering or splice-affecting, 109 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 413, Silent 109, Nonsense Mutation 30, Frame Shift Del 13, Splice Site 10, Intron 7, Splice Region 6, 3'UTR 5, RNA 4, 5'Flank 2, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.105G>T p.M35I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV64290238, COSV64295455; called by muse, mutect2, varscan2
- TP53 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | catalogued as rs869312782, COSV52692559, COSV52721885, COSV53153630, COSV53758203; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.419T>C p.F140S (on ENST00000297504 / NM_001282291.2; = p.F123S on NM_007188.5) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99873663; called by muse, mutect2, varscan2
- ABCC11 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV62321387, COSV62322737; called by muse, mutect2, varscan2
- ACBD5 | c.1274A>T p.Q425L (on ENST00000375888 / NM_001352568.1; = p.Q416L on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.776); catalogued as COSV65518908; called by muse, mutect2, varscan2
- ACSL5 | c.422A>G p.N141S (on ENST00000354273; = p.N197S on NM_016234.3) | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1464092678, COSV61130265; called by muse, mutect2, varscan2
- ADAM30 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 20/245 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV65560948; called by muse, mutect2
- ADAMTS10 | c.303C>A p.H101Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as COSV99546401; called by muse, mutect2, varscan2
- ADGRL3 | c.2516C>A p.T839K (on ENST00000506720 / NM_001322402.2; = p.T771K on NM_015236.6) | Missense Mutation (SNP) | VAF 21/239 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.229); catalogued as COSV72230385; called by muse, mutect2
- ADH7 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as rs373728468, COSV52920563; called by muse, mutect2, varscan2
- ADHFE1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52554827; called by muse, mutect2, varscan2
- AHNAK | c.7182C>A p.H2394Q | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV57211665; called by muse, mutect2, varscan2
- ANK1 | c.4784C>A p.A1595D | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV55879798; called by muse, mutect2, varscan2
- ANO2 | c.1329C>A p.F443L (on ENST00000356134 / NM_001278597.3; = p.F447L on NM_001278596.3) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV59019885, COSV59030174; called by muse, mutect2, varscan2
- APLNR | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as rs1288189384, COSV57242175; called by muse, mutect2, varscan2
- ARFGEF2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64211924; called by muse, mutect2
- ARFGEF3 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.313); catalogued as COSV52455911; called by muse, mutect2, varscan2
- ARHGAP21 | c.4180A>G p.K1394E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57604953; called by muse, mutect2, varscan2
- ARHGEF16 | c.1291C>G p.P431A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65681875; called by muse, mutect2, varscan2
- ARHGEF40 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV53879860; called by muse, mutect2, varscan2
- ARSF | c.283+1G>T p.X95_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63839452; called by muse, mutect2, varscan2
- ASTN1 | c.2199C>G p.N733K | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV56067269; called by muse, mutect2, varscan2
- ATP10B | c.4015C>A p.P1339T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV59149700; called by muse, mutect2, varscan2
- ATP1A3 | c.2879G>T p.G960V (on ENST00000545399 / NM_001256214.2; = p.G947V on NM_152296.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV57487055; called by muse, mutect2, varscan2
- ATP8B2 | c.1140G>T p.E380D (on ENST00000672630; = p.E347D on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59245765; called by muse, mutect2, varscan2
- B3GALT1 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV59908554; called by muse, mutect2, varscan2
- BCHE | c.1645T>C p.F549L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.906); catalogued as COSV52256121; called by muse, mutect2, varscan2
- BCLAF1 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.431); catalogued as COSV50357518; called by muse, mutect2, varscan2
- BEX2 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV101012771; called by muse, mutect2, varscan2
- BIRC7 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV53900939; called by muse, mutect2
- BMP1 | c.105G>C p.E35D | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.216); catalogued as COSV59244224; called by muse, mutect2, varscan2
- BMPER | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.589); catalogued as COSV51816845; called by muse, mutect2, varscan2
- BMS1 | c.3756G>C p.K1252N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65733691; called by muse, mutect2, varscan2
- BNC2 | c.3141G>T p.K1047N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66164131; called by muse, mutect2, varscan2
- BPHL | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV66743428; called by muse, mutect2
- BRD8 | c.1257C>G p.I419M (on ENST00000254900 / NM_139199.2; = p.I492M on NM_006696.4) | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50147530; called by muse, mutect2
- BRINP1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV56298187; called by muse, mutect2, varscan2
- BRINP2 | c.2155C>G p.Q719E | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as COSV64177154; called by muse, mutect2, varscan2
- C2CD2L | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.186); catalogued as COSV60883935; called by muse, mutect2
- C3orf20 | c.1693C>T p.L565= | Splice Region (SNP) | VAF 14/64 reads (22%) | catalogued as COSV53784738, COSV99514369; called by muse, mutect2, varscan2
- C5orf38 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs571510621, COSV57409593, COSV57410889; called by muse, mutect2
- C6 | c.2103G>T p.R701= | Splice Region (SNP) | VAF 101/145 reads (70%) | catalogued as COSV54709231, COSV99666709; called by muse, mutect2, varscan2
- C9orf72 | c.505-1G>T p.X169_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV66154713; called by muse, mutect2, varscan2
- CACHD1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51552300; called by muse, mutect2
- CACNA1A | c.3937C>A p.R1313S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV64196442; called by muse, mutect2, varscan2
- CACNA1E | c.5106C>A p.Y1702* | Nonsense Mutation (SNP) | VAF 40/184 reads (22%) | catalogued as COSV62391598; called by muse, mutect2, varscan2
- CACNA1S | c.5473G>C p.V1825L | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.97); catalogued as rs764984855, COSV62938891; called by muse, mutect2, varscan2
- CACNA2D1 | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV62378030, COSV62381138; called by muse, mutect2, varscan2
- CACNG3 | c.446A>T p.N149I | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50066953; called by muse, mutect2, varscan2
- CALN1 | c.649G>A p.G217S (on ENST00000329008 / NM_001017440.3; = p.G259S on NM_031468.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1296688169, COSV61129452; called by muse, mutect2, varscan2
- CARD11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62716698, COSV62717202; called by muse, mutect2, varscan2
- CASS4 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV64386196; called by muse, mutect2, varscan2
- CCN3 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52383689; called by muse, mutect2
- CCNB3 | c.4125G>T p.L1375F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52072591; called by muse, mutect2, varscan2
- CD101 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.575); catalogued as COSV56717607, COSV99055133; called by muse, mutect2, varscan2
- CD151 | c.695G>T p.C232F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV58989749; called by mutect2, varscan2
- CD1D | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 67/331 reads (20%) | catalogued as COSV63808900; called by muse, mutect2, varscan2
- CD300LG | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs756282737, COSV53223621; called by muse, mutect2, varscan2
- CDCA7 | c.147+1G>T p.X49_splice | Splice Site (SNP) | VAF 20/92 reads (22%) | catalogued as COSV60720301; called by muse, mutect2, varscan2
- CDH12 | c.1393A>T p.S465C | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV66400571; called by muse, mutect2, varscan2
- CDH2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99295477; called by muse, mutect2, varscan2
- CDH26 | c.711C>T p.T237= | Splice Region (SNP) | VAF 9/52 reads (17%) | catalogued as rs201340865, COSV54846133; called by muse, mutect2, varscan2
- CDH9 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50260214; called by muse, mutect2
- CDHR3 | c.744A>T p.E248D | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58416231; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5278A>T p.S1760C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV62573777; called by muse, mutect2, varscan2
- CEP170 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763874401, COSV60508412; called by muse, mutect2
- CER1 | c.476G>T p.W159L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV66603156; called by muse, mutect2, varscan2
- CHL1 | c.1157T>A p.I386N (on ENST00000397491 / NM_001253387.1; = p.I402N on NM_006614.4) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56591544; called by muse, mutect2, varscan2
- CHRM4 | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.407); catalogued as COSV100641747; called by muse, mutect2
- CHRND | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.144); catalogued as COSV51318577; called by muse, mutect2, varscan2
- CHST8 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754261375, COSV52858201, COSV52858327; called by muse, mutect2, varscan2
- CLCN1 | c.1108C>A p.R370S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58369380; called by muse, mutect2
- CNR1 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62987036; called by muse, mutect2
- CNTN5 | c.1657G>T p.G553W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54305268; called by muse, mutect2, varscan2
- CNTNAP2 | c.3798C>G p.G1266= | Splice Region (SNP) | VAF 6/55 reads (11%) | catalogued as COSV62171814; called by muse, varscan2
- CNTNAP5 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV70483391, COSV70486352; called by muse, mutect2
- COBL | c.2465A>T p.H822L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54344017; called by muse, mutect2, varscan2
- CORO6 | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV61470665; called by muse, mutect2, varscan2
- CPO | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 41/158 reads (26%) | catalogued as COSV55939556; called by muse, mutect2, varscan2
- CRACD | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51719802; called by muse, mutect2, varscan2
- CRTAM | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV57067676; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.248); catalogued as COSV65677009, COSV65677054; called by muse, mutect2, varscan2
- CSMD2 | c.1205-2A>T p.X402_splice | Splice Site (SNP) | VAF 11/100 reads (11%) | catalogued as COSV53906231; called by muse, mutect2, varscan2
- CSMD3 | c.9387T>A p.D3129E (on ENST00000297405 / NM_001363185.1; = p.D2960E on NM_052900.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.858); catalogued as COSV52162838; called by muse, mutect2, varscan2
- CTNND2 | c.1472A>G p.Y491C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1307654389, COSV58883812; called by muse, mutect2
- CYP11B1 | c.1298G>C p.G433A | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV52826465; called by muse, mutect2, varscan2
- DAB2IP | c.3076A>T p.R1026W (on ENST00000408936; = p.R998W on NM_032552.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52258168; called by muse, mutect2
- DAOA | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.146); catalogued as COSV61602215; called by muse, mutect2, varscan2
- DAOA | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.039); catalogued as COSV61602221; called by muse, mutect2, varscan2
- DDX41 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV57903137; called by muse, mutect2, varscan2
- DEFA4 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52404644; called by muse, mutect2, varscan2
- DGKB | c.1664C>A p.T555K | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.13); catalogued as COSV51777938; called by muse, mutect2, varscan2
- DGKI | c.2474C>G p.S825C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV55947063; called by muse, mutect2, varscan2
- DLC1 | c.3442G>A p.D1148N (on ENST00000276297 / NM_001348081.2; = p.D711N on NM_006094.5) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV52300637; called by muse, mutect2, varscan2
- DLGAP1 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV59799570; called by muse, mutect2, varscan2
- DMBT1 | c.7573G>A p.V2525I (on ENST00000338354 / NM_001377530.1; = p.V1768I on NM_004406.3) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as rs755743749, COSV57541855; called by muse, mutect2, varscan2
- DMRTB1 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV65112952; called by muse, mutect2, varscan2
- DMXL1 | c.8234A>G p.N2745S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60709932, COSV60713737; called by muse, mutect2, varscan2
- DNAH7 | c.7760G>T p.R2587I | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56761195, COSV56761995; called by muse, mutect2, varscan2
- DNAH9 | c.9937C>T p.L3313F | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371926599, COSV52346452; called by muse, mutect2, varscan2
- DNAI3 | c.2264C>A p.S755Y | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.344); catalogued as COSV54002040; called by muse, mutect2, varscan2
- DNMT3A | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53049179; called by muse, mutect2
- DOCK9 | c.2294G>A p.G765E (on ENST00000376460 / NM_001366676.2; = p.G766E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV59626625; called by muse, mutect2, varscan2
- DPP3 | c.2042-1G>T p.X681_splice | Splice Site (SNP) | VAF 18/156 reads (12%) | catalogued as COSV59148283; called by muse, mutect2
- DPY19L4 | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV68962745; called by muse, mutect2, varscan2
- DRGX | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100938356, COSV65136146; called by muse, mutect2, varscan2
- DSC2 | c.2635G>C p.D879H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51864031; called by muse, mutect2, varscan2
- DSCAM | c.2472G>T p.E824D | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.415); catalogued as COSV68025541; called by muse, mutect2, varscan2
- EDN3 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV61107729; called by muse, mutect2, varscan2
- EFTUD2 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130202, COSV53655499; called by muse, mutect2, varscan2
- ELAPOR2 | c.2999T>A p.L1000Q (on ENST00000450689 / NM_001142749.3; = p.L833Q on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51886139; called by muse, mutect2
- EMSY | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58259603; called by muse, mutect2, varscan2
- ENAM | c.3221C>G p.S1074C | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs761340961, COSV68535794; called by muse, mutect2, varscan2
- ENPP2 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as rs1252523976, COSV50013610; called by muse, mutect2, varscan2
- EPG5 | c.1321A>C p.M441L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56348585; called by muse, mutect2, varscan2
- EPHA1 | c.416G>T p.R139L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51970809, COSV51975526; called by muse, mutect2, varscan2
- EPHA5 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56641780, COSV56683112; called by muse, mutect2, varscan2
- EPHB1 | c.815C>A p.A272E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV67659601; called by muse, mutect2, varscan2
- EPHB6 | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV67418268, COSV67419244; called by muse, mutect2, varscan2
- ERBB4 | c.2483C>A p.A828D | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61482216; called by muse, mutect2, varscan2
- ERN1 | c.1890C>A p.C630* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV101458363; called by muse, mutect2
- EVPL | c.5623G>A p.E1875K | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV56910105; called by muse, mutect2
- EXO1 | c.1438A>T p.R480* | Nonsense Mutation (SNP) | VAF 28/153 reads (18%) | catalogued as COSV62217276; called by muse, mutect2, varscan2
- EXOC4 | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.312); catalogued as COSV54095244, COSV54107266; called by muse, mutect2, varscan2
- EXPH5 | c.4132G>C p.D1378H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV56201401; called by muse, mutect2, varscan2
- FAF1 | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV65638087; called by muse, mutect2
- FAM102A | c.459G>A p.K153= (on ENST00000373095 / NM_001035254.3; = p.K11= on NM_203305.2) | Splice Region (SNP) | VAF 19/80 reads (24%) | catalogued as COSV55947813; called by muse, mutect2, varscan2
- FAM171A1 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV65315574; called by muse, mutect2, varscan2
- FAM221A | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1396984668, COSV61387720; called by muse, mutect2, varscan2
- FAM71C | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60943093; called by muse, mutect2, varscan2
- FAM78A | c.685G>T p.A229S | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55992100, COSV55992182; called by muse, mutect2, varscan2
- FANCM | c.3611G>T p.R1204L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57500239, COSV57501138; called by muse, mutect2, varscan2
- FAT3 | c.1123A>T p.R375* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV53102697, COSV53139363; called by muse, mutect2, varscan2
- FAT3 | c.4493A>T p.H1498L | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.327); catalogued as COSV53102723; called by muse, mutect2, varscan2
- FAT3 | c.4852C>A p.P1618T | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53102741; called by muse, mutect2, varscan2
- FAT3 | c.12733T>A p.S4245T | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV53102755; called by muse, mutect2, varscan2
- FBP1 | c.862G>T p.V288F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV64689266; called by muse, mutect2, varscan2
- FBXL7 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV73492583; called by muse, mutect2, varscan2
- FLG | c.5431G>C p.D1811H | Missense Mutation (SNP) | VAF 45/850 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV64240859, COSV64244065; called by muse, mutect2
- FLG2 | c.4316G>T p.R1439I | Missense Mutation (SNP) | VAF 168/582 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as COSV66168240; called by muse, mutect2, varscan2
- FLG2 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 183/762 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV66168247; called by muse, mutect2, varscan2
- FMO1 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61445481; called by muse, mutect2, varscan2
- FOXB2 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV65022880; called by muse, mutect2, varscan2
- FOXL2NB | c.203C>G p.S68W | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV57726722; called by muse, mutect2, varscan2
- FRAS1 | c.3343A>T p.I1115F | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV53605974; called by muse, mutect2, varscan2
- FSTL5 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60192279; called by muse, mutect2, varscan2
- FXR1 | c.949A>T p.R317* | Nonsense Mutation (SNP) | VAF 42/102 reads (41%) | catalogued as COSV99976058; called by muse, mutect2, varscan2
- FYB1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 257/348 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60945306; called by muse, mutect2, varscan2
- FZD7 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53809153; called by muse, mutect2, varscan2
- GABRG2 | c.483C>A p.H161Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62717509; called by muse, mutect2, varscan2
- GARNL3 | c.1440G>T p.E480D | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV59225712; called by muse, mutect2, varscan2
- GATB | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56130256; called by muse, mutect2, varscan2
- GFI1 | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV54042449, COSV99647341, COSV99647625; called by muse, varscan2
- GHR | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100050963, COSV50111108; called by muse, mutect2, varscan2
- GIMAP6 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV100188062, COSV61033781; called by muse, mutect2, varscan2
- GLI2 | c.4019G>T p.G1340V (on ENST00000361492 / NM_001374353.1; = p.G1357V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.139); catalogued as COSV58040294; called by muse, mutect2, varscan2
- GPR141 | c.259T>C p.F87L | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as COSV57731223, COSV57732088; called by muse, mutect2
- GPR158 | c.3230A>C p.Q1077P | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1445707158, COSV66268986; called by muse, mutect2
- GPR158 | c.3232G>C p.G1078R | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66268989; called by muse, mutect2
- GPR35 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV60577051; called by muse, mutect2, varscan2
- GPR37 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58256607; called by muse, mutect2, varscan2
- GRAMD1B | c.1253A>C p.K418T | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.134); catalogued as COSV59203279; called by muse, mutect2
- GREM2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV58950057; called by muse, mutect2
- GSTM3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1274809271, COSV56662024; called by muse, mutect2, varscan2
- GTF2I | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60400976; called by muse, mutect2
- GTF3C2 | c.2450G>T p.R817L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV51990221; called by mutect2, varscan2
- GUCY1A1 | c.2072A>T p.*691Lext*15 | Nonstop Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV56651149; called by muse, mutect2, varscan2
- HARS2 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51226953; called by muse, mutect2, varscan2
- HDAC9 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67771975; called by muse, mutect2, varscan2
- HELZ | c.5133G>T p.Q1711H | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV62377982; called by muse, mutect2, varscan2
- HINFP | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV63431929; called by muse, mutect2, varscan2
- HIVEP3 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 70/270 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.2); catalogued as COSV56014171; called by muse, mutect2, varscan2
- HNF4A | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57382209; called by muse, mutect2, varscan2
- HRH4 | c.584T>C p.M195T | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56927929; called by muse, mutect2, varscan2
- HTR3B | c.1028G>C p.R343P | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as COSV52744180, COSV99492192; called by muse, mutect2, varscan2
- IFNB1 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV66525294; called by muse, mutect2, varscan2
- IGKV3-15 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs773811103; called by muse, mutect2, varscan2
- IGSF10 | c.6841C>T p.L2281F | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56376636; called by muse, mutect2, varscan2
- IKZF1 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100497902; called by muse, mutect2, varscan2
- IKZF1 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497903; called by muse, mutect2, varscan2
- IL17A | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV60684405; called by muse, mutect2, varscan2
- IL32 | c.659A>T p.E220V (on ENST00000396890 / NM_001308078.4; = p.E174V on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV50404251; called by muse, mutect2
- IMPG1 | c.1885A>G p.R629G | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV64057130; called by muse, mutect2, varscan2
- INCENP | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV53915034; called by muse, mutect2, varscan2
- INHBB | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.638); catalogued as COSV54677778; called by muse, mutect2, varscan2
- INO80 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as rs774135495, COSV62737653; called by muse, mutect2
- INSYN1 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.201); catalogued as rs756759221, COSV65837349; called by muse, mutect2, varscan2
- INTS7 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV65344196; called by muse, mutect2, varscan2
- IRF2BPL | c.2023C>G p.R675G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53146902; called by muse, mutect2, varscan2
- IRS4 | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV64533508; called by muse, mutect2, varscan2
- ISM2 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.049); catalogued as COSV53634780; called by muse, mutect2, varscan2
- ITGAL | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63321851; called by muse, mutect2, varscan2
- ITGAM | c.588C>G p.F196L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV54936475; called by muse, mutect2, varscan2
- ITPRID1 | c.425T>A p.I142K | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60073382; called by muse, mutect2, varscan2
- JAM2 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV57255435; called by muse, mutect2, varscan2
- JPH1 | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100646428, COSV60610372; called by muse, mutect2, varscan2
- KCNK13 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV56412695; called by muse, mutect2, varscan2
- KCTD8 | c.112del p.A38Hfs*8 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as COSV100759404; called by mutect2, pindel
- KLHL14 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV63832104; called by muse, mutect2, varscan2
- KPRP | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as COSV64221481; called by muse, mutect2, varscan2
- KRT38 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV55845853; called by muse, mutect2, varscan2
- LAMA1 | c.6127C>A p.L2043M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV67535920; called by muse, mutect2, varscan2
- LAMC1 | c.2540G>C p.G847A | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51138966; called by muse, mutect2, varscan2
- LAP3 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV56899579; called by muse, mutect2, varscan2
- LCE2D | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV64228954, COSV64229059; called by muse, mutect2, varscan2
- LDLRAD4 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63336595; called by muse, mutect2, varscan2
- LIFR | c.3151A>T p.N1051Y | Missense Mutation (SNP) | VAF 150/285 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV54689057; called by muse, mutect2, varscan2
- LNPK | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV55823466; called by muse, mutect2, varscan2
- LRFN5 | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.225); catalogued as COSV53253653, COSV53263769; called by muse, mutect2, varscan2
- LRP1B | c.5651C>T p.S1884F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67199539; called by muse, mutect2, varscan2
- LRP4 | c.917A>G p.N306S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV66135433; called by muse, mutect2
- LRRC52 | c.599T>A p.I200K | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.01); catalogued as COSV54231912; called by muse, mutect2, varscan2
- LRRTM1 | c.550T>G p.C184G | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54440541; called by muse, mutect2, varscan2
- LYST | c.9544G>C p.D3182H | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs777743654, COSV101090496, COSV67706397, COSV67714985; called by muse, mutect2
- MAGEB1 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66775652; called by muse, mutect2, varscan2
- MAGEB6 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV66872166, COSV66872383; called by muse, mutect2, varscan2
- MAP2 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.438); catalogued as COSV52288808; called by muse, mutect2, varscan2
- MAP9 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV60904471; called by muse, mutect2, varscan2
- MAS1L | c.327G>C p.M109I | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101009631, COSV101009634; called by muse, mutect2, varscan2
- MATN4 | c.1654G>C p.G552R (on ENST00000372754; = p.G511R on NM_003833.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | PolyPhen benign (0.175); catalogued as rs929647038, COSV61351216; called by muse, mutect2, varscan2
- MCEMP1 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as COSV58039899; called by muse, mutect2, varscan2
- MDC1 | c.2207G>T p.S736I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64524332; called by muse, mutect2, varscan2
- MEIOC | c.2126T>A p.L709* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV63439869; called by muse, mutect2, varscan2
- MEOX1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1257047496, COSV59355921; called by muse, mutect2, varscan2
- MEOX2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV56289387; called by muse, mutect2, varscan2
- METAP1D | c.710T>A p.I237K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV59929853; called by muse, mutect2, varscan2
- MGAM | c.4718A>T p.Q1573L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs955618611, COSV72074518; called by muse, mutect2, varscan2
- MLLT10 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100307356; called by muse, mutect2, varscan2
- MMRN1 | c.3638A>C p.K1213T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53336761; called by muse, mutect2, varscan2
- MRPS5 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV55533461; called by muse, mutect2, varscan2
- MTNR1A | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775674720, COSV56154968, COSV56156196; called by muse, mutect2, varscan2
- MUC16 | c.35084C>A p.P11695Q | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV101200404, COSV67461966; called by muse, varscan2
- MUC17 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 145/542 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs141608296, COSV60280453; called by muse, mutect2, varscan2
- MUC5B | c.9350G>A p.R3117K | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1233790161, COSV101500205, COSV71591656; called by muse, mutect2, varscan2
- MYCBPAP | c.363C>A p.S121= | Splice Region (SNP) | VAF 47/167 reads (28%) | catalogued as COSV60407252; called by muse, mutect2, varscan2
- MYF5 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 28/98 reads (29%) | catalogued as COSV57354956; called by muse, mutect2
- MYF5 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57354965; called by muse, mutect2
- MYH1 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV56847138; called by muse, mutect2, varscan2
- MYH4 | c.3870G>T p.E1290D | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV55117069; called by muse, mutect2, varscan2
- MYH6 | c.1957C>A p.H653N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62449761; called by muse, mutect2, varscan2
- MYOF | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs555479300, COSV63703270, COSV63704165; called by muse, mutect2, varscan2
- NALCN | c.2909G>T p.C970F | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as COSV51931749, COSV51944323; called by muse, mutect2, varscan2
- NCOA2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1026744704, COSV101475919, COSV71763864; called by muse, mutect2, varscan2
- NCSTN | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV54101629; called by muse, mutect2, varscan2
- NDUFAF5 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65246775; called by muse, mutect2, varscan2
- NECTIN1 | c.187A>T p.T63S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.056); catalogued as COSV50599179; called by muse, mutect2, varscan2
- NID1 | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV51619028; called by muse, mutect2, varscan2
- NIPAL4 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); catalogued as rs371714489, COSV57428005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKIRAS2 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56917764; called by mutect2, varscan2
- NLE1 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV62604088; called by muse, mutect2, varscan2
- NLGN1 | c.2076G>C p.L692F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64331264; called by muse, mutect2, varscan2
- NLRP3 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60223275; called by muse, mutect2, varscan2
- NOS1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as COSV57611201; called by muse, mutect2, varscan2
- NOTCH4 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV66680302; called by muse, mutect2, varscan2
- NPC1L1 | c.1682-2A>G p.X561_splice | Splice Site (SNP) | VAF 30/95 reads (32%) | catalogued as COSV56924466; called by muse, mutect2, varscan2
- NPR3 | c.588C>A p.H196Q | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV54086881; called by muse, mutect2
- NPY5R | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100642832, COSV58451788; called by muse, mutect2, varscan2
- NRAP | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 39/254 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV100748344, COSV63489937; called by muse, mutect2, varscan2
- NRP2 | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); catalogued as COSV55927110; called by muse, mutect2, varscan2
- NTRK2 | c.2141T>A p.M714K (on ENST00000323115 / NM_001369534.1; = p.M730K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52862170; called by muse, mutect2, varscan2
- OR10J1 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.092); catalogued as COSV71128732; called by muse, mutect2, varscan2
- OR1L1 | c.436G>T p.E146* (on ENST00000373686; = p.E96* on NM_001005236.3) | Nonsense Mutation (SNP) | VAF 38/279 reads (14%) | catalogued as COSV58935500; called by muse, varscan2
- OR2J2 | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 58/263 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV65847935; called by muse, varscan2
- OR2J2 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65847939; called by muse, varscan2
- OR2M5 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 60/680 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV63545634, COSV63546108; called by muse, mutect2
- OR4A5 | c.802A>G p.M268V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); catalogued as COSV60522325; called by muse, mutect2, varscan2
- OR4C15 | c.767G>T p.S256I (on ENST00000314644; = p.S202I on NM_001001920.2) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV58952464, COSV58953494; called by muse, mutect2, varscan2
- OR4D5 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58306653; called by muse, mutect2, varscan2
- OR4E2 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV57731661; called by muse, mutect2, varscan2
- OR51V1 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV58314912, COSV58315461; called by muse, mutect2, varscan2
- OR52N2 | c.226T>A p.C76S | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV57676692; called by muse, mutect2, varscan2
- OR5B17 | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62160222; called by muse, mutect2, varscan2
- OR5M10 | c.663T>G p.I221M | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV73242300; called by muse, mutect2
- OR9G1 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56450059; called by muse, mutect2
- OSER1 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54853566; called by muse, mutect2, varscan2
- PABPC1 | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59400908; called by muse, mutect2, varscan2
- PAPPA | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV60281945; called by muse, mutect2, varscan2
- PAPPA2 | c.3619G>T p.V1207F | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV62796137; called by muse, mutect2, varscan2
- PBXIP1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.124); catalogued as rs751951283, COSV63777068; called by muse, mutect2, varscan2
- PCDH10 | c.1928G>T p.R643L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV52092502; called by muse, mutect2, varscan2
- PCDHA2 | c.1363T>A p.F455I | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65366537; called by muse, mutect2, varscan2
- PCDHA5 | c.767G>T p.S256I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as COSV65351719; called by muse, mutect2, varscan2
- PCDHB6 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554277464, COSV50694919; called by muse, mutect2, varscan2
- PCDHGA4 | c.1416A>T p.Q472H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.005); catalogued as COSV53935151; called by muse, mutect2, varscan2
- PCLO | c.13099G>T p.V4367F | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61631015; called by muse, mutect2, varscan2
- PCMTD1 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.069); catalogued as COSV62120085; called by muse, mutect2, varscan2
- PCNX3 | c.2092G>A p.G698R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as COSV63136336; called by muse, mutect2, varscan2
- PCSK7 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV56118493; called by muse, mutect2, varscan2
- PDCD11 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV58915575; called by muse, mutect2, varscan2
- PDHA2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV54778797; called by muse, mutect2, varscan2
- PDILT | c.1512G>C p.L504F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV56701447; called by muse, mutect2, varscan2
- PDZRN3 | c.1572C>A p.H524Q | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as COSV55197604; called by muse, mutect2, varscan2
- PEX19 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 110/347 reads (32%) | catalogued as COSV63619191, COSV63619406; called by muse, mutect2, varscan2
- PIGA | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61237491; called by muse, mutect2, varscan2
- PIGQ | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50313079; called by muse, mutect2, varscan2
- PKD1 | c.4513G>T p.G1505C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51914739; called by muse, mutect2, varscan2
- PKD1L1 | c.1666A>T p.K556* | Nonsense Mutation (SNP) | VAF 59/135 reads (44%) | catalogued as COSV56963435, COSV56964226; called by muse, mutect2, varscan2
- PLCB1 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.719); catalogued as COSV62048168; called by muse, mutect2, varscan2
- PLEKHB2 | c.56G>T p.W19L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52175579; called by muse, mutect2, varscan2
- PLEKHM3 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV66816403; called by muse, mutect2, varscan2
- PLPPR4 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV64569125; called by muse, mutect2, varscan2
- PNLIP | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV65040293; called by muse, mutect2, varscan2
- PNPLA1 | c.696G>T p.L232F (on ENST00000394571 / NM_001374623.1; = p.L137F on NM_173676.2) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.739); catalogued as rs1421066093, COSV57233916; called by muse, mutect2, varscan2
- POLL | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV54574748; called by muse, mutect2, varscan2
- PRAMEF15 | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1245857928; called by muse, mutect2, varscan2
- PRKAG1 | c.368A>T p.Q123L | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV60292405; called by muse, mutect2, varscan2
- PRKG1 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100907224, COSV64769618; called by muse, mutect2, varscan2
- PROKR2 | c.37A>C p.N13H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.106); catalogued as COSV54086263; called by muse, mutect2, varscan2
- PSG11 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as rs371455452, COSV60454885; called by muse, mutect2, varscan2
- PSMB11 | c.80G>C p.W27S | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV101273397; called by muse, mutect2
- PSMB11 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV101273398; called by muse, mutect2
- PTGFRN | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs746038245, COSV67798333, COSV67799022; called by muse, mutect2, varscan2
- PTGS2 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV66568967; called by muse, mutect2, varscan2
- PTGS2 | c.694C>A p.L232I | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV66568978; called by muse, mutect2, varscan2
- PTPRD | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV61941210, COSV61947266; called by muse, mutect2, varscan2
- R3HDML | c.464C>A p.P155Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53835776; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1275-2A>G p.X425_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57928360; called by muse, mutect2, varscan2
- RAB39B | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV65624570; called by muse, mutect2, varscan2
- RASSF2 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RBM12B | c.1978A>T p.R660W | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV67897822; called by muse, mutect2, varscan2
- RBM15 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV63923415; called by muse, mutect2, varscan2
- RGS1 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV66505199; called by muse, mutect2, varscan2
- RGS6 | c.992A>C p.K331T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV59574538; called by muse, mutect2
- RHBDD1 | c.73A>T p.N25Y | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV58126262; called by muse, mutect2, varscan2
- RHBDL2 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV56707871; called by muse, mutect2, varscan2
- RICTOR | c.3240G>C p.K1080N | Missense Mutation (SNP) | VAF 22/634 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV57120985; called by muse, mutect2
- RIF1 | c.4057G>C p.D1353H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV54616165; called by muse, mutect2, varscan2
- RNF20 | c.2093A>T p.E698V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs1233041263, COSV66660944; called by muse, mutect2, varscan2
- ROPN1L | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 78/174 reads (45%) | catalogued as COSV56873625, COSV56874510; called by muse, mutect2, varscan2
- RPGRIP1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52848973; called by muse, mutect2
- RPRD2 | c.1334T>G p.L445W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV64819721; called by muse, mutect2, varscan2
- RTL3 | c.1106T>C p.I369T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs1344439662, COSV58183971; called by muse, mutect2, varscan2
- RUFY2 | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56259308; called by muse, mutect2, varscan2
- RUNDC3B | c.994C>T p.L332F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56692684; called by muse, mutect2, varscan2
- RYR1 | c.2047G>A p.V683M | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62095498; called by muse, mutect2, varscan2
- RYR2 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368014180; called by muse, mutect2, varscan2
- RYR2 | c.10361G>A p.R3454H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1229045575, COSV63681265; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV101211896; called by muse, mutect2, varscan2
- RYR3 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV101211897; called by muse, mutect2, varscan2
- RYR3 | c.12380G>A p.G4127D (on ENST00000389232; = p.G4128D on NM_001036.6) | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV66786097; called by muse, mutect2, varscan2
- SAMD9 | c.4635C>G p.I1545M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV66074730; called by muse, mutect2, varscan2
- SCG2 | c.1361C>A p.P454H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.552); catalogued as COSV59539757; called by muse, mutect2, varscan2
- SCN4A | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV71126579; called by muse, mutect2, varscan2
- SDF2 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55931686; called by muse, mutect2, varscan2
- SERPINB13 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.64); catalogued as rs770383989, COSV54027244; called by mutect2, varscan2
- SFMBT2 | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62808699; called by muse, mutect2, varscan2
- SH3PXD2A | c.1372G>T p.E458* (on ENST00000369774 / NM_001365079.1; = p.E430* on NM_014631.2) | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV60116911, COSV60117343, COSV60118677; called by muse, mutect2, varscan2
- SIPA1L2 | c.3619G>T p.D1207Y | Missense Mutation (SNP) | VAF 121/581 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV53389170; called by muse, mutect2, varscan2
- SLC16A6 | c.1080C>A p.Y360* | Nonsense Mutation (SNP) | VAF 37/144 reads (26%) | catalogued as COSV59177125; called by muse, mutect2, varscan2
- SLC17A1 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV55078527; called by muse, mutect2, varscan2
- SLC25A13 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs199744651, COSV55706361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A24 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51447248; called by muse, mutect2
- SLC5A4 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as COSV56669888; called by muse, mutect2, varscan2
- SLC6A15 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as COSV57022861; called by muse, mutect2, varscan2
- SLC6A5 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV54225797; called by muse, mutect2, varscan2
- SMC6 | c.2206G>T p.V736L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV100704726; called by muse, varscan2
- SNX7 | c.640-2A>T p.X214_splice | Splice Site (SNP) | VAF 19/70 reads (27%) | catalogued as COSV60267968; called by muse, mutect2, varscan2
- SORCS1 | c.3165+1G>T p.X1055_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV53860751; called by muse, mutect2, varscan2
- SOX6 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57044030; called by muse, mutect2, varscan2
- SPRED1 | c.550A>G p.R184G | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs1188036457, COSV54435823; called by muse, mutect2, varscan2
- SPTAN1 | c.1446G>C p.W482C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63986723; called by muse, mutect2, varscan2
- SPX | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV57020579; called by muse, mutect2, varscan2
- ST3GAL5 | c.255A>T p.L85F | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.162); catalogued as COSV60385571; called by muse, mutect2, varscan2
- ST8SIA5 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | PolyPhen benign (0.062); catalogued as COSV100164466, COSV100164743; called by muse, mutect2
- STAB2 | c.2679C>A p.H893Q | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV66338130; called by muse, mutect2, varscan2
- STARD13 | c.2276A>G p.Y759C (on ENST00000336934 / NM_001243476.3; = p.Y641C on NM_052851.3) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553359255, COSV55229952; called by muse, mutect2, varscan2
- STK36 | c.3116G>T p.R1039L | Missense Mutation (SNP) | VAF 57/265 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV55325994; called by muse, mutect2, varscan2
- STK38 | c.317T>A p.V106D | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV57708664; called by muse, varscan2
- SULF2 | c.747C>A p.S249R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63415543; called by muse, mutect2, varscan2
- SYNE1 | c.4186G>T p.A1396S (on ENST00000367255 / NM_182961.4; = p.A1403S on NM_033071.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1183983383, COSV54965715; called by muse, mutect2, varscan2
- SYT11 | c.1065G>C p.L355F | Missense Mutation (SNP) | VAF 149/611 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV64174148; called by muse, mutect2, varscan2
- SYT3 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100143826; called by muse, mutect2, varscan2
- SYT7 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV55655330; called by muse, mutect2, varscan2
- TAAR2 | c.491T>A p.L164Q (on ENST00000367931 / NM_001033080.1; = p.L119Q on NM_014626.3) | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs961064449, COSV51579008; called by muse, mutect2
- TAF1C | c.2183G>T p.R728L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV58985569, COSV58985961; called by muse, mutect2, varscan2
- TAF1L | c.2866G>T p.A956S | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV54261108; called by muse, mutect2, varscan2
- TAF3 | c.2177A>G p.E726G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60205719; called by muse, mutect2, varscan2
- TAFA5 | c.153C>A p.D51E (on ENST00000402357 / NM_001082967.3; = p.D44E on NM_015381.7) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV60976847, COSV60992706; called by muse, mutect2, varscan2
- TBC1D15 | c.1079T>C p.L360P | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59848930; called by muse, mutect2, varscan2
- TBC1D9 | c.2582T>G p.L861R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV71307335; called by muse, mutect2, varscan2
- TCHH | c.3316C>G p.R1106G | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV64274390; called by muse, mutect2, varscan2
- TCL1B | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV61551935; called by muse, mutect2, varscan2
- TENM1 | c.1469C>A p.S490* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV64424887, COSV64430687; called by muse, mutect2, varscan2
- TENM2 | c.2767C>A p.P923T (on ENST00000518659 / NM_001122679.2; = p.P691T on NM_001080428.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs745686658, COSV69128457; called by muse, mutect2, varscan2
- TENM4 | c.8021G>T p.C2674F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV53624138; called by muse, mutect2, varscan2
- TG | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99598704; called by muse, mutect2, varscan2
- TG | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as COSV99598707; called by muse, mutect2, varscan2
- TGFB1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs1332127818, COSV55724613; called by muse, mutect2, varscan2
- TGFBR3 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.285); catalogued as COSV53021233, COSV53030626; called by mutect2, varscan2
- TGFBR3 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV53024749; called by muse, mutect2
- THSD7B | c.2938C>A p.P980T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.667); catalogued as COSV99743384; called by muse, mutect2, varscan2
- TICAM1 | c.1047C>G p.C349W | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.297); catalogued as COSV50231720; called by muse, mutect2, varscan2
- TLDC2 | c.497T>C p.M166T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV53429293; called by muse, mutect2
- TM6SF1 | c.446T>A p.M149K | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV51943551, COSV51944049; called by muse, mutect2, varscan2
- TM9SF2 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV64506655; called by muse, mutect2, varscan2
- TMEM255A | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556019904, COSV59028981; called by muse, varscan2
- TMEM255A | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59028989; called by muse, varscan2
- TMEM62 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV53040907; called by muse, mutect2, varscan2
- TMEM74 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV52463062; called by muse, mutect2, varscan2
- TMEM89 | c.406A>T p.I136F | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56571688; called by muse, mutect2, varscan2
- TNXB | c.8410A>T p.K2804* (on ENST00000647633; = p.K2557* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV64478013; called by muse, mutect2, varscan2
- TOGARAM1 | c.2776A>G p.K926E | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.465); catalogued as COSV63891726; called by muse, mutect2, varscan2
- TOX2 | c.239C>A p.P80Q (on ENST00000358131 / NM_001098798.2; = p.P29Q on NM_032883.3) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57885448; called by muse, mutect2, varscan2
- TPTE | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs780491487; called by muse, varscan2
- TRIB2 | c.764A>G p.H255R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50225153; called by muse, mutect2, varscan2
- TRIM15 | c.912C>A p.S304R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as COSV100938777; called by muse, mutect2, varscan2
- TRIM58 | c.1157T>A p.L386Q | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63569943; called by muse, mutect2, varscan2
- TRIP13 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV51319747; called by muse, mutect2, varscan2
- TRPM1 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV56633695; called by muse, mutect2, varscan2
- TRPS1 | c.1750C>A p.P584T (on ENST00000220888 / NM_001330599.2; = p.P597T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV55237479, COSV55254966; called by muse, mutect2, varscan2
- TRPV6 | c.947C>G p.T316S | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.96); catalogued as rs754397407, COSV63891489; called by muse, mutect2, varscan2
- TTN | c.68165C>A p.A22722D (on ENST00000591111; = p.A15298D on NM_003319.4) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | PolyPhen possibly damaging (0.491); catalogued as COSV60010374; called by muse, mutect2
- TTN | c.52430G>T p.G17477V (on ENST00000591111; = p.G10053V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV60010412; called by muse, mutect2
- TTN | c.32834C>A p.P10945Q (on ENST00000591111; = p.P10018Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | PolyPhen possibly damaging (0.839); catalogued as rs770211782, COSV60010451; called by muse, mutect2, varscan2
- TTN | c.6835C>A p.P2279T (on ENST00000591111; = p.P2233T on NM_003319.4) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | PolyPhen possibly damaging (0.676); catalogued as COSV60010477, COSV60170613; called by muse, mutect2
- TYR | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54474168; called by muse, mutect2, varscan2
- UBAP2L | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV55171680; called by muse, mutect2, varscan2
- UBL4B | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.367); catalogued as COSV61944374; called by muse, mutect2, varscan2
- UGT2B11 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV71423264; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51954853; called by muse, mutect2, varscan2
- USH2A | c.13081C>A p.P4361T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV56360474; called by muse, mutect2, varscan2
- USH2A | c.1835C>T p.T612I | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56360491; called by muse, mutect2, varscan2
- USP7 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214251; called by muse, mutect2, varscan2
- VAC14 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55751249, COSV55752959; called by muse, mutect2, varscan2
- VCP | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV62720347; called by muse, mutect2, varscan2
- VEZT | c.197C>T p.T66I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV54138268; called by muse, mutect2, varscan2
- WAC | c.857C>G p.S286C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100611114, COSV61567489; called by muse, mutect2, varscan2
- WASHC5 | c.1718G>T p.R573M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59195930; called by muse, mutect2, varscan2
- WNT10A | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV51462276; called by muse, mutect2, varscan2
- ZBTB25 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67198538; called by muse, mutect2, varscan2
- ZEB1 | c.2890A>T p.K964* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV58042615; called by muse, mutect2, varscan2
- ZFYVE16 | c.2833C>T p.P945S | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV62015459; called by muse, mutect2, varscan2
- ZGRF1 | c.2833G>T p.G945* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs925454132, COSV52200175; called by muse, mutect2, varscan2
- ZIC1 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV51552824, COSV51553658; called by muse, mutect2, varscan2
- ZIM3 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54141946, COSV54142127; called by muse, mutect2, varscan2
- ZNF236 | c.5482G>T p.E1828* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV53486759; called by muse, mutect2, varscan2
- ZNF263 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV54596246; called by muse, mutect2, varscan2
- ZNF324B | c.287G>C p.R96P | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60741556; called by muse, mutect2, varscan2
- ZNF334 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs763384880, COSV61617978; called by muse, mutect2, varscan2
- ZNF423 | c.1793A>G p.N598S (on ENST00000563137 / NM_001379286.1; = p.N590S on NM_015069.4) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV52185814; called by muse, mutect2, varscan2
- ZNF496 | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV54176412; called by muse, mutect2
- ZNF518B | c.1090T>C p.F364L | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs1483611882, COSV58722241; called by muse, mutect2, varscan2
- ZNF532 | c.2684G>T p.G895V | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV60172786; called by muse, mutect2, varscan2
- ZNF572 | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100073780; called by muse, mutect2, varscan2
- ZNF572 | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as COSV100073781; called by muse, mutect2, varscan2
- ZNF585A | c.542T>C p.M181T (on ENST00000292841 / NM_001288800.2; = p.M126T on NM_152655.3) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1287381562, COSV53063195; called by muse, mutect2, varscan2
- ZP4 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV63911761; called by muse, mutect2, varscan2
- ZSCAN10 | c.1891G>T p.G631C (on ENST00000252463; = p.G686C on NM_032805.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52967723, COSV99373907; called by muse, mutect2, varscan2
- ZSCAN10 | c.953G>T p.G318V (on ENST00000252463; = p.G373V on NM_032805.3) | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV52967737; called by muse, mutect2, varscan2
- ADAM23 | c.1451del p.L484Yfs*81 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | called by pindel, varscan2
- C17orf78 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CRMP1 | c.201del p.G68Efs*16 | Frame Shift Del (DEL) | VAF 13/125 reads (10%) | called by mutect2, pindel, varscan2
- DNAH17 | c.13089C>A p.D4363E | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.101); called by muse, mutect2
- DSC1 | c.956dup p.L320Vfs*17 | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- EEF1E1 | c.235del p.V79Sfs*4 | Frame Shift Del (DEL) | VAF 42/254 reads (17%) | called by mutect2, pindel, varscan2
- FOXP2 | c.938del p.H313Lfs*4 | Frame Shift Del (DEL) | VAF 16/176 reads (9%) | called by mutect2, pindel
- FRG2C | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- H3C6 | c.243del p.D82Tfs*9 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- IGHA2 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 87/265 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCND2 | c.1429del p.Q477Sfs*100 | Frame Shift Del (DEL) | VAF 21/153 reads (14%) | called by mutect2, pindel, varscan2
- KIR2DL1 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.045); called by muse, varscan2
- LCN8 | c.224+1del p.X75_splice (on ENST00000612714 / NM_001345934.1; = p.X52_splice on NM_178469.3) | Splice Site (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- MAMDC4 | c.3394_3407del p.A1132Pfs*61 (on ENST00000445819; = p.A1053Pfs*61 on NM_206920.3) | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel, varscan2
- MORF4L1 | c.876del p.M293Cfs*11 (on ENST00000331268 / NM_206839.2; = p.M254Cfs*11 on NM_006791.4) | Frame Shift Del (DEL) | VAF 40/161 reads (25%) | called by mutect2, pindel, varscan2
- MUC16 | c.35158del p.A11720Pfs*13 | Frame Shift Del (DEL) | VAF 50/185 reads (27%) | called by pindel, varscan2
- MUC16 | c.4458dup p.A1487Cfs*12 | Frame Shift Ins (INS) | VAF 49/205 reads (24%) | called by mutect2, pindel, varscan2
- MUC2 | c.3730G>T p.G1244C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- OR2T4 | c.764_768delinsCAACT p.L255P | Missense Mutation (ONP) | VAF 13/112 reads (12%) | called by mutect2*, pindel
- PCSK1 | c.1897_1898del p.Q633Rfs*4 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by pindel, varscan2
- SNX7 | c.460del p.T154Lfs*2 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- TAF15 | c.1237G>A p.G413R (on ENST00000605844 / NM_139215.3; = p.G410R on NM_003487.4) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TRAV7 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZFHX4 | c.1889del p.G630Vfs*3 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ABCB8 | c.420T>C p.F140= (on ENST00000297504 / NM_001282291.2; = p.F123= on NM_007188.5) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99873671; called by muse, mutect2, varscan2
- ABTB2 | c.3015G>A p.L1005= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1256311783, COSV54387301; called by muse, mutect2, varscan2
- ACE | c.813C>A p.I271= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV52005991; called by muse, mutect2, varscan2
- ACTN2 | c.1392C>A p.I464= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV63971447, COSV63972072; called by muse, mutect2, varscan2
- ADGRL2 | c.1668T>C p.A556= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV54664519; called by muse, mutect2, varscan2
- ADGRL2 | c.1899A>G p.Q633= (on ENST00000370717 / NM_001366005.1; = p.Q620= on NM_012302.4) | Silent (SNP) | VAF 18/121 reads (15%) | catalogued as COSV54664555; called by muse, mutect2, varscan2
- ADSS2 | c.1215C>T p.L405= | Silent (SNP) | VAF 19/199 reads (10%) | catalogued as rs1387263143, COSV63694982; called by muse, mutect2
- AHNAK | c.13497A>G p.E4499= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV57211652; called by muse, mutect2, varscan2
- ALDH1L1 | c.381T>C p.D127= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV56413375; called by muse, mutect2
- ALPK2 | c.1521G>T p.G507= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as rs776962818, COSV64492495; called by muse, varscan2
- ANKS1B | c.1854C>T p.S618= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as COSV61347913; called by muse, mutect2, varscan2
- ARFGEF1 | c.999A>G p.V333= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV51607050; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.795C>T p.C265= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV63437636; called by muse, mutect2, varscan2
- ATP5F1E | c.138G>A p.V46= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV53886555; called by muse, mutect2, varscan2
- C2CD3 | c.4980G>T p.S1660= | Silent (SNP) | VAF 20/171 reads (12%) | catalogued as COSV58092633, COSV58098736; called by muse, mutect2, varscan2
- CADM3 | c.672T>A p.S224= (on ENST00000368125 / NM_001127173.3; = p.S258= on NM_021189.5) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV63685169; called by muse, mutect2
- CDC42EP4 | c.144G>A p.G48= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV59962647; called by muse, mutect2, varscan2
- CDH2 | c.456C>A p.G152= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99295479; called by muse, mutect2
- CFAP47 | c.1338G>T p.T446= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52883737, COSV52883923; called by muse, mutect2, varscan2
- CSN2 | c.273G>T p.L91= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV61992062; called by muse, mutect2, varscan2
- CTH | c.1134G>T p.V378= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV61008145; called by muse, mutect2, varscan2
- CTTNBP2 | c.3570G>A p.K1190= | Silent (SNP) | VAF 8/184 reads (4%) | catalogued as COSV50397545; called by muse, mutect2
- CYP11B1 | c.756G>A p.V252= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV52826477; called by muse, mutect2
- DACT1 | c.1092T>A p.A364= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV60020494; called by muse, mutect2, varscan2
- DIO3 | c.903C>G p.P301= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100832023, COSV63772979; called by mutect2, varscan2
- DNAH11 | c.10494C>A p.P3498= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV60953110; called by muse, mutect2, varscan2
- DNAI2 | c.1557G>T p.L519= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV56758279, COSV56763153; called by muse, mutect2
- DOCK9 | c.2634C>T p.L878= (on ENST00000376460 / NM_001366676.2; = p.L879= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV59626594; called by muse, mutect2
- DSG3 | c.1773C>T p.N591= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV57125782; called by muse, mutect2, varscan2
- EFNA1 | c.537C>A p.I179= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100310192; called by muse, mutect2, varscan2
- ELAPOR1 | c.2928C>A p.T976= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100884400; called by muse, mutect2
- EMILIN2 | c.1515C>A p.L505= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV54423055; called by muse, mutect2, varscan2
- EPC1 | c.231A>T p.P77= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV53925390; called by muse, mutect2, varscan2
- ERICH3 | c.4092G>A p.E1364= | Silent (SNP) | VAF 49/180 reads (27%) | catalogued as rs1346917974, COSV100446118, COSV58605180; called by muse, mutect2, varscan2
- EYS | c.108C>A p.P36= | Silent (SNP) | VAF 33/177 reads (19%) | catalogued as rs1014843963, COSV60976139; called by muse, mutect2, varscan2
- FAM135B | c.3631C>A p.R1211= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV52720502; called by muse, mutect2, varscan2
- FAM214A | c.111A>T p.V37= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV55923759; called by muse, mutect2, varscan2
- FAT4 | c.4110G>C p.G1370= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as COSV67885021; called by muse, mutect2, varscan2
- FBXL13 | c.561G>A p.L187= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV57537382; called by muse, mutect2, varscan2
- FLNC | c.1668C>A p.I556= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV57954907; called by muse, mutect2, varscan2
- FXR1 | c.948G>T p.V316= | Silent (SNP) | VAF 44/105 reads (42%) | catalogued as COSV99976057; called by muse, mutect2, varscan2
- GAD2 | c.969A>G p.K323= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as COSV52156029; called by muse, mutect2, varscan2
- GIMAP6 | c.864G>T p.G288= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs762393240, COSV100188058, COSV61033191; called by muse, mutect2, varscan2
- GMEB1 | c.861T>C p.V287= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV53794125; called by muse, mutect2, varscan2
- GUCY1A2 | c.1314A>G p.L438= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV56481561; called by muse, mutect2, varscan2
- HS3ST2 | c.537C>A p.P179= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV54461171; called by muse, mutect2, varscan2
- IGHM | c.735G>A p.L245= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.120C>A p.T40= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- IGHV3-73 | c.108C>G p.S36= | Silent (SNP) | VAF 39/195 reads (20%) | called by muse, mutect2, varscan2
- IL17A | c.400C>A p.R134= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs764987987, COSV100391392; called by muse, mutect2, varscan2
- KIF19 | c.699G>T p.R233= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100739005, COSV63429313; called by muse, mutect2, varscan2
- LAMB1 | c.4173A>G p.S1391= | Silent (SNP) | VAF 14/274 reads (5%) | catalogued as COSV55963910; called by muse, mutect2
- LPAR1 | c.348G>T p.L116= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV62688464; called by muse, mutect2, varscan2
- MAP3K19 | c.3417C>T p.F1139= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV59638256; called by muse, mutect2
- MASP1 | c.1713C>T p.I571= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as COSV61825940; called by muse, mutect2, varscan2
- MATK | c.885C>T p.I295= (on ENST00000310132 / NM_139355.3; = p.I296= on NM_002378.4) | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV59554299; called by mutect2, varscan2
- MPO | c.1086G>T p.L362= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV56563307; called by muse, mutect2, varscan2
- MUC16 | c.4911G>A p.G1637= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as rs758725951, COSV67461971; called by muse, mutect2, varscan2
- MYH6 | c.9T>C p.D3= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as rs1445736744, COSV62449767; called by muse, mutect2, varscan2
- NAGLU | c.552G>C p.L184= | Silent (SNP) | VAF 17/228 reads (7%) | catalogued as COSV56794706; called by muse, mutect2
- NAV3 | c.4209G>T p.T1403= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs367571223, COSV57075854; called by muse, mutect2, varscan2
- NCAM1 | c.702G>C p.V234= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV57515162; called by muse, mutect2, varscan2
- NEUROD6 | c.273G>A p.R91= | Silent (SNP) | VAF 34/324 reads (10%) | catalogued as rs778117324, COSV51771207; called by muse, mutect2, varscan2
- NLRP12 | c.1849T>C p.L617= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV100144814, COSV60746426; called by muse, mutect2, varscan2
- NOTCH4 | c.3615G>T p.L1205= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV66680299; called by muse, mutect2, varscan2
- NPAS4 | c.1299C>G p.G433= | Silent (SNP) | VAF 83/256 reads (32%) | catalogued as COSV60650098, COSV60650142, COSV60650418; called by muse, mutect2, varscan2
- OR4D10 | c.189C>A p.L63= | Silent (SNP) | VAF 78/256 reads (30%) | catalogued as COSV73260012; called by muse, mutect2, varscan2
- OR5D13 | c.615C>A p.A205= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as COSV62333477; called by muse, mutect2, varscan2
- PABPC1 | c.1521C>T p.T507= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV59400898; called by muse, mutect2, varscan2
- PAPPA2 | c.813G>T p.R271= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV62777136; called by muse, mutect2, varscan2
- PCDH11X | c.1569T>A p.T523= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV53460060; called by muse, mutect2, varscan2
- PCDHGA3 | c.1911G>T p.A637= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV53925634, COSV53935127; called by muse, mutect2, varscan2
- PCED1B | c.927C>A p.R309= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV71395122; called by muse, mutect2, varscan2
- PCF11 | c.1542G>T p.S514= | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV53527893; called by muse, mutect2, varscan2
- PIK3CG | c.1203C>G p.P401= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV63247777; called by muse, mutect2
- PLCL1 | c.2943C>A p.L981= | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV70827625; called by muse, mutect2, varscan2
- PPRC1 | c.3684C>T p.L1228= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as rs953921218, COSV53384868; called by muse, mutect2, varscan2
- PTPRD | c.5214C>A p.T1738= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV61941182; called by muse, mutect2, varscan2
- RTL9 | c.1554A>G p.T518= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV71825511; called by muse, mutect2, varscan2
- SERPINA1 | c.795G>A p.L265= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs749044003, COSV63345586; called by muse, mutect2, varscan2
- SGO2 | c.1227G>A p.K409= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV63414978; called by muse, varscan2
- SHOX2 | c.36T>C p.F12= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV55827506; called by muse, mutect2, varscan2
- SIK3 | c.3159A>G p.Q1053= (on ENST00000445177 / NM_001366686.2; = p.Q1011= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1565368567, COSV52613167; called by mutect2, varscan2
- SLC12A3 | c.1410G>T p.L470= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV99343768; called by muse, mutect2
- SLC33A1 | c.162G>T p.G54= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV63947066; called by muse, mutect2, varscan2
- SLC4A4 | c.3207A>G p.S1069= (on ENST00000264485 / NM_001098484.3; = p.S1025= on NM_003759.4) | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV52622673; called by muse, mutect2, varscan2
- SLC6A17 | c.1401C>T p.I467= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV58992684; called by muse, mutect2, varscan2
- SLC6A4 | c.804C>T p.F268= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as COSV55566599; called by muse, mutect2, varscan2
- SPICE1 | c.748A>C p.R250= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV55620019; called by muse, mutect2, varscan2
- SPTA1 | c.5220C>T p.D1740= | Silent (SNP) | VAF 62/217 reads (29%) | catalogued as COSV63752185; called by muse, mutect2, varscan2
- SRRM3 | c.687C>T p.S229= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV58386885; called by muse, mutect2, varscan2
- STMN2 | c.519C>T p.L173= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55219135; called by muse, mutect2, varscan2
- TAS2R14 | c.583C>T p.L195= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV67855275; called by muse, mutect2, varscan2
- TG | c.2913C>G p.G971= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV55073610; called by muse, mutect2, varscan2
- TG | c.8004C>A p.P2668= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99598710; called by muse, mutect2
- TMCC2 | c.345C>A p.S115= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV58002722; called by muse, mutect2, varscan2
- TNXB | c.9582G>A p.P3194= (on ENST00000647633; = p.P2947= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs536634503, COSV64478006, COSV64482070; called by muse, mutect2, varscan2
- TRAPPC11 | c.1578G>A p.L526= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV58216096; called by muse, mutect2, varscan2
- TRBC2 | c.99C>A p.A33= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- TRIO | c.6369G>T p.L2123= | Silent (SNP) | VAF 22/337 reads (7%) | catalogued as COSV60082418; called by muse, mutect2
- TRMT2B | c.363C>G p.L121= | Silent (SNP) | VAF 78/243 reads (32%) | catalogued as COSV58619343; called by muse, mutect2, varscan2
- UGT1A10 | c.312T>C p.S104= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV60837219; called by muse, mutect2, varscan2
- WASF1 | c.198C>A p.V66= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55619479; called by muse, mutect2, varscan2
- WDR72 | c.3294C>T p.P1098= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV64745738; called by muse, mutect2, varscan2
- WFIKKN2 | c.318C>A p.P106= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV60958540; called by muse, mutect2, varscan2
- ZFPM2 | c.261G>T p.P87= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs755810063, COSV68274575, COSV68280427; called by muse, mutect2, varscan2
- ZMYM4 | c.4302A>T p.S1434= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV58909648; called by muse, mutect2, varscan2
- ZNF33A | c.1644G>A p.G548= (on ENST00000458705 / NM_006974.3; = p.G549= on NM_006954.2) | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as COSV56724537; called by muse, mutect2
- ZNF629 | c.2595A>T p.P865= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV52698222; called by muse, mutect2, varscan2
- AC024940.1 | n.3258G>C | RNA (SNP) | VAF 37/101 reads (37%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821190 G>T | 3'Flank (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- C7orf66 | n.394G>T | RNA (SNP) | VAF 24/82 reads (29%) | catalogued as rs554132290; called by muse, mutect2, varscan2
- CCL13 | c.*2C>A | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as rs779852870, COSV99861657; called by muse, mutect2, varscan2
- CHMP1A | c.*13G>T | 3'UTR (SNP) | VAF 9/37 reads (24%) | catalogued as rs749676630, COSV99498221, COSV99498233; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415322 G>T | 5'Flank (SNP) | VAF 22/86 reads (26%) | catalogued as COSV52567449, COSV52568789; called by muse, mutect2, varscan2
- DCHS2 | n.2375C>A | RNA (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100252094, COSV59724489; called by muse, mutect2, varscan2
- GH2 | c.457-34G>A | Intron (SNP) | VAF 21/118 reads (18%) | catalogued as rs375084233, COSV60427974; called by muse, mutect2, varscan2
- KIRREL2 | c.*12dup | 3'UTR (INS) | VAF 38/142 reads (27%) | called by mutect2, varscan2
- KIRREL2 | c.*13delinsTT | 3'UTR (INS) | VAF 33/176 reads (19%) | called by mutect2*, pindel, varscan2*
- LRRFIP1 | c.154-1718G>T | Intron (SNP) | VAF 29/175 reads (17%) | catalogued as COSV99790300; called by muse, mutect2, varscan2
- PRR12 | chr19:49595178 C>T | 5'Flank (SNP) | VAF 9/25 reads (36%) | catalogued as COSV55870037; called by muse, varscan2
- PRR12 | c.51+415G>T | Intron (SNP) | VAF 10/58 reads (17%) | catalogued as COSV55870043; called by muse, mutect2, varscan2
- RBM44 | c.-98-2973C>T | Intron (SNP) | VAF 16/66 reads (24%) | catalogued as COSV57629108; called by muse, mutect2, varscan2
- RBM44 | c.-98-1811G>A | Intron (SNP) | VAF 5/63 reads (8%) | catalogued as COSV57629123; called by muse, mutect2
- RPL13A | c.342+68A>G | Intron (SNP) | VAF 11/67 reads (16%) | catalogued as rs767747586, COSV99201267; called by muse, mutect2, varscan2
- RPS26P15 | n.280G>A | RNA (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- SOX9 | c.*2G>A | 3'UTR (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99818118; called by muse, mutect2, varscan2
- TPH2 | c.609-10889C>T | Intron (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100421842; called by muse, mutect2, varscan2
